Somatic mutation profile of tumor specimen ALCH-B1V9-TTP1-A (aliquot ALCH-B1V9-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1V9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.7 years (23,267 days).
Specimen ALCH-B1V9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a61f5922-8e70-4328-8a56-ebd591000342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1V9-NB1-A (Blood Derived Normal), aliquot ALCH-B1V9-NB1-A-5-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a38d35-1537-4731-8b1b-6e1020d59720

The open-access MAF lists 155 somatic variants for this specimen: 112 protein-altering or splice-affecting, 25 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 25, Intron 9, Nonsense Mutation 9, Splice Site 4, 5'UTR 4, RNA 4, Frame Shift Del 4, Splice Region 1, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 33/381 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA7 | c.3884G>T p.R1295L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs374965623, COSV54032755; called by muse, mutect2, varscan2
- ADGRB3 | c.2964G>T p.W988C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53251093; called by muse, varscan2
- ANKRD18B | c.2932A>G p.I978V | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as rs528857560; called by muse, mutect2
- ANKS1B | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100248054; called by muse, mutect2
- ARHGAP4 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1557102420; called by muse, mutect2
- BECN1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1490494506; called by muse, varscan2
- CACNA1G | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs1363009203, COSV61724626; called by muse, varscan2
- CCT8L2 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100742897; called by muse, mutect2, varscan2
- CDH18 | c.1801C>A p.H601N | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs943129056; called by muse, mutect2
- CHRM2 | c.852T>G p.N284K | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.101); catalogued as COSV57785765; called by muse, mutect2
- CNTN1 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); catalogued as COSV100751343; called by muse, mutect2
- COL24A1 | c.121+2T>A p.X41_splice | Splice Site (SNP) | VAF 26/181 reads (14%) | catalogued as rs777556997; called by muse, mutect2, varscan2
- CSMD2 | c.8326C>A p.H2776N | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV99588537; called by muse, mutect2
- DES | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs397516690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.4484A>G p.Q1495R | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747709832; called by muse, mutect2, varscan2
- FAM47A | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV100649974, COSV60495260; called by muse, mutect2, varscan2
- FOXN4 | c.1324G>T p.G442* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV54493535; called by muse, mutect2
- FOXN4 | c.1323G>T p.E441D | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772062598, COSV100142247; called by muse, mutect2
- GLRA2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs777077152, COSV54341910; called by mutect2, varscan2
- LRRC69 | c.754-1G>T p.X252_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | catalogued as rs1280194634; called by muse, mutect2
- MGAM | c.4514G>T p.G1505V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414495073, COSV101527731; called by muse, mutect2, varscan2
- MYH9 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as rs1304469257, COSV53383079, COSV53387833; called by muse, mutect2
- NLGN4X | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV52038087; called by mutect2, varscan2
- NOS1AP | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100723496; called by muse, mutect2, varscan2
- OPLAH | c.1913del p.G638Afs*25 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as COSV70677110; called by mutect2, pindel, varscan2
- PCDHA2 | c.1389C>G p.F463L | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.636); catalogued as COSV65371698; called by muse, mutect2, varscan2
- PHF14 | c.1046-1G>T p.X349_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as rs1314646817; called by muse, mutect2
- PIWIL4 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs554791169, COSV100133076; called by muse, mutect2
- PRAMEF1 | c.970C>A p.H324N | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.357); catalogued as COSV60014394; called by muse, mutect2
- RFX5 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as rs780878545; called by muse, mutect2
- RGPD2 | c.78G>T p.L26F | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59529981; called by muse, mutect2, varscan2
- SPATA13 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as rs1371876337; called by muse, mutect2
- TEAD1 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 39/381 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs1426099840; called by muse, mutect2, varscan2
- TNFRSF8 | c.753C>A p.D251E | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as rs536842664, COSV55796217; called by muse, mutect2, varscan2
- TNP2 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV57130100; called by muse, mutect2
- TOPAZ1 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100554890; called by muse, mutect2, varscan2
- TTN | c.18523A>G p.K6175E (on ENST00000591111; = p.K5248E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | PolyPhen benign (0.007); catalogued as rs781106189, COSV60227648; called by muse, mutect2
- VWF | c.4073G>A p.S1358N | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.455); catalogued as CM135810; called by muse, mutect2, varscan2
- ZNF106 | c.3052C>T p.R1018* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs760386511; called by mutect2, varscan2
- ZNF184 | c.1673A>T p.Y558F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as COSV53004479; called by muse, mutect2, varscan2
- ZNF236 | c.4024G>A p.G1342R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1186411982; called by muse, mutect2, varscan2
- ZNF256 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376934863; called by muse, mutect2, varscan2
- ZNF536 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs1349300963, COSV100835729, COSV62822647; called by muse, mutect2
- ADAM10 | c.1801A>T p.K601* | Nonsense Mutation (SNP) | VAF 32/316 reads (10%) | called by muse, mutect2
- ADAMTS17 | c.622A>T p.K208* | Nonsense Mutation (SNP) | VAF 23/268 reads (9%) | called by muse, mutect2
- ANKRD30B | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3625G>C p.A1209P | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ARID4A | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ASXL1 | c.4165G>T p.G1389W | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMI1 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.086); called by muse, mutect2
- BPTF | c.6292T>A p.S2098T | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.232); called by muse, mutect2
- CD58 | c.744C>T p.N248= | Splice Region (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- CDH10 | c.1194A>T p.E398D | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CFHR4 | c.1166C>A p.P389Q (on ENST00000367416 / NM_001201551.2; = p.P143Q on NM_006684.5) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CHP2 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CLCA4 | c.1697C>A p.A566E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2
- CNTNAP1 | c.3779T>A p.V1260E | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CPN1 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CSMD3 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- EFCAB12 | c.1459A>T p.R487W | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAM43A | c.21C>G p.H7Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- GGTA1 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRXCR2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- HDAC9 | c.1577G>T p.S526I | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- HECW1 | c.913G>T p.V305F | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGLV3-9 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIFC3 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 31/333 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.313); called by muse, mutect2
- KLHL1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT5 | c.18T>A p.S6R | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- LRRC69 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- LRRIQ1 | c.3903C>A p.D1301E | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- LRRIQ1 | c.3904A>C p.S1302R | Missense Mutation (SNP) | VAF 38/421 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2
- MED12L | c.5800G>A p.A1934T | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- METTL22 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); called by muse, mutect2
- NPAP1 | c.3180C>A p.D1060E | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OR4C5 | c.798del p.C267Vfs*9 | Frame Shift Del (DEL) | VAF 37/372 reads (10%) | called by mutect2, pindel, varscan2
- OR52B6 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR5AS1 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2
- OR8G1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- P3H2 | c.2075A>T p.Q692L | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PAH | c.1104G>C p.E368D | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALLD | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCARE | c.3217C>A p.P1073T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, varscan2
- PCDHGB2 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCGF5 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PCLO | c.11875A>G p.I3959V | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.183); called by muse, mutect2
- PLCB1 | c.2354C>A p.T785K | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- POLQ | c.1960-2A>T p.X654_splice | Splice Site (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- PREX1 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2
- PTPRB | c.1837C>A p.L613I | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRR | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PYHIN1 | c.884A>G p.D295G | Missense Mutation (SNP) | VAF 9/302 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2
- RBFOX1 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SCN7A | c.1441del p.T481Lfs*3 | Frame Shift Del (DEL) | VAF 19/192 reads (10%) | called by mutect2, pindel
- SERPINB12 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SFI1 | c.2344C>A p.H782N (on ENST00000400288 / NM_001007467.3; = p.H751N on NM_014775.4) | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- SLC8A1 | c.2614G>C p.G872R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLCO5A1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK3 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- SPANXN2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRFBP1 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2
- TAGLN3 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- TEP1 | c.4221C>G p.H1407Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TIAM1 | c.4561G>T p.D1521Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TTL | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- UNC13A | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- UNC5B | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB21 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- ZFHX4 | c.6687del p.R2230Efs*27 | Frame Shift Del (DEL) | VAF 28/213 reads (13%) | called by mutect2, pindel, varscan2
- ZIM3 | c.83_84dup p.Q29Nfs*9 | Frame Shift Ins (INS) | VAF 26/210 reads (12%) | called by mutect2, varscan2
- ZNF599 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACADSB | c.861A>C p.I287= | Silent (SNP) | VAF 64/521 reads (12%) | called by muse, mutect2, varscan2
- BEND4 | c.1473C>A p.V491= | Silent (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- DEDD2 | c.852G>T p.L284= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- DNAH9 | c.8313A>T p.V2771= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- DOCK10 | c.5742C>G p.L1914= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as rs770103343; called by muse, mutect2
- GPR158 | c.174G>C p.S58= | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- HAS1 | c.1335G>A p.K445= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- HCLS1 | c.1404A>T p.G468= | Silent (SNP) | VAF 28/299 reads (9%) | called by muse, mutect2
- LEMD3 | c.15A>G p.A5= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as rs1476285077; called by muse, mutect2
- MBOAT2 | c.1381T>C p.L461= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- METTL22 | c.12G>T p.L4= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.19887A>T p.I6629= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- OR1N1 | c.399C>G p.V133= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- OR6B1 | c.330A>T p.T110= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- PROM2 | c.45C>G p.G15= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- RBM19 | c.2758C>A p.R920= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs766739457; called by muse, mutect2, varscan2
- SLC12A1 | c.1101A>G p.A367= | Silent (SNP) | VAF 35/294 reads (12%) | called by muse, mutect2, varscan2
- SNTG1 | c.1137C>A p.A379= | Silent (SNP) | VAF 35/272 reads (13%) | catalogued as COSV52465188, COSV99384299; called by muse, mutect2, varscan2
- SOD3 | c.264G>C p.A88= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2784C>A p.I928= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- STRA8 | c.120G>T p.L40= (on ENST00000275764; = p.L18= on NM_182489.2) | Silent (SNP) | VAF 18/334 reads (5%) | catalogued as rs1315325193; called by muse, mutect2
- TIAM1 | c.4560G>T p.V1520= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- USP11 | c.129G>T p.A43= | Silent (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2
- WDR25 | c.597A>T p.P199= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ZNF90 | c.318T>C p.R106= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- AC092818.1 | n.400G>T | RNA (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2, varscan2
- ANO10 | c.1669-1671del | Intron (DEL) | VAF 28/263 reads (11%) | catalogued as rs1559685924; called by mutect2, pindel, varscan2
- C22orf34 | n.2099G>T | RNA (SNP) | VAF 12/156 reads (8%) | catalogued as rs950496663; called by muse, mutect2
- C5orf58 | c.-36G>A | 5'UTR (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- CCDC39 | c.2266-547C>A | Intron (SNP) | VAF 14/108 reads (13%) | called by muse, varscan2
- CCDC39 | c.2266-548C>A | Intron (SNP) | VAF 14/105 reads (13%) | called by muse, varscan2
- CD300C | c.-12C>A | 5'UTR (SNP) | VAF 9/121 reads (7%) | catalogued as rs779995113; called by muse, mutect2
- CNTN4 | c.56-245C>G | Intron (SNP) | VAF 23/279 reads (8%) | called by muse, mutect2
- CXCL12 | c.266+895C>A | Intron (SNP) | VAF 16/214 reads (7%) | catalogued as COSV59107866; called by muse, mutect2
- DPH6 | c.*1A>G | 3'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- IL16 | c.3805+73G>T | Intron (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- KCNMA1 | c.2267-4452A>T | Intron (SNP) | VAF 25/348 reads (7%) | called by muse, mutect2
- KLRA1P | n.459G>A | RNA (SNP) | VAF 13/201 reads (6%) | called by muse, mutect2
- MYH3 | c.5658+15T>A | Intron (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- OR2L1P | n.505G>T | RNA (SNP) | VAF 44/370 reads (12%) | called by muse, mutect2, varscan2
- PSMA1 | c.-20G>T | 5'UTR (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- PSRC1 | c.-4G>A | 5'UTR (SNP) | VAF 15/159 reads (9%) | catalogued as rs1239620467; called by muse, mutect2
- ZNF252P | n.245+3033C>T | Intron (SNP) | VAF 5/64 reads (8%) | catalogued as rs1167797794; called by muse, mutect2
